Somatic mutation profile of tumor specimen C3L-01954-01 (aliquot CPT0100590009) from CPTAC case C3L-01954, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 67.7 years (24,719 days).
Specimen C3L-01954-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21df198e-c2ed-41f1-9c48-32857c09274f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01954-31 (Blood Derived Normal), aliquot CPT0101990002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40c6bba8-f387-4d0c-8bab-a718de8b2780

The open-access MAF lists 87 somatic variants for this specimen: 65 protein-altering or splice-affecting, 13 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 13, Frame Shift Del 10, Intron 8, Splice Site 6, Nonsense Mutation 5, In Frame Del 4, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM8 | c.2258C>T p.P753L | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs545492149; called by muse, mutect2, varscan2
- CACNA1S | c.1909G>A p.V637M | Missense Mutation (SNP) | VAF 99/330 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62939268; called by muse, mutect2, varscan2
- CACNA2D2 | c.2937G>A p.W979* (on ENST00000479441 / NM_001174051.3; = p.W972* on NM_006030.4) | Nonsense Mutation (SNP) | VAF 89/285 reads (31%) | catalogued as rs965093324; called by muse, mutect2, varscan2
- GIMAP1 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.97); catalogued as rs775693608, COSV56187833; called by muse, mutect2, varscan2
- KRTDAP | c.261+1G>C p.X87_splice | Splice Site (SNP) | VAF 74/250 reads (30%) | catalogued as rs1421681541; called by muse, mutect2, varscan2
- MYH8 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 137/503 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1169419511, COSV101238084; called by muse, mutect2, varscan2
- NEFM | c.2374G>T p.A792S | Missense Mutation (SNP) | VAF 175/326 reads (54%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs1417383202; called by muse, mutect2, varscan2
- NUTM2G | c.1286T>C p.I429T | Missense Mutation (SNP) | VAF 106/406 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs766581847; called by muse, mutect2, varscan2
- POLN | c.904G>T p.A302S | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.107); catalogued as COSV67027904; called by muse, mutect2, varscan2
- POP5 | c.21-1G>A p.X7_splice | Splice Site (SNP) | VAF 92/285 reads (32%) | catalogued as rs1194794002; called by muse, mutect2, varscan2
- RPL3L | c.469T>C p.C157R | Missense Mutation (SNP) | VAF 100/499 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as rs774727364; called by muse, mutect2, varscan2
- ABCC6 | c.1850C>G p.S617* | Nonsense Mutation (SNP) | VAF 276/594 reads (46%) | called by muse, mutect2
- ACIN1 | c.1078G>T p.E360* | Nonsense Mutation (SNP) | VAF 108/452 reads (24%) | called by mutect2, varscan2
- ACIN1 | c.1077G>C p.K359N | Missense Mutation (SNP) | VAF 105/465 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- AQP7 | c.421T>C p.F141L | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- ARMCX4 | c.829G>A p.A277T (on ENST00000433011; = p.A173T on NM_001256155.2) | Missense Mutation (SNP) | VAF 111/362 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CCN1 | c.694C>A p.Q232K | Missense Mutation (SNP) | VAF 140/535 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CELSR2 | c.2784_2785del p.F929Cfs*18 | Frame Shift Del (DEL) | VAF 64/218 reads (29%) | called by pindel, varscan2
- CUBN | c.5629_5630del p.N1877Lfs*16 | Frame Shift Del (DEL) | VAF 149/582 reads (26%) | called by mutect2, pindel, varscan2
- CWH43 | c.1504del p.W502Gfs*12 | Frame Shift Del (DEL) | VAF 31/107 reads (29%) | called by mutect2, pindel, varscan2
- DDX52 | c.1541C>T p.T514I | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH7 | c.5750A>C p.Q1917P | Missense Mutation (SNP) | VAF 76/208 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ELOC | c.275A>G p.E92G | Missense Mutation (SNP) | VAF 77/159 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- EMSY | c.2278A>T p.I760L | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FANCB | c.342T>A p.S114R | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GAB3 | c.1549del p.S517Pfs*2 | Frame Shift Del (DEL) | VAF 40/165 reads (24%) | called by mutect2, pindel, varscan2
- IGSF3 | c.1779T>G p.H593Q (on ENST00000369486 / NM_001007237.3; = p.H613Q on NM_001542.4) | Missense Mutation (SNP) | VAF 96/338 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INTS4 | c.295_296del p.L99Ifs*14 | Frame Shift Del (DEL) | VAF 38/151 reads (25%) | called by mutect2, pindel, varscan2
- KLK2 | c.279C>G p.S93R | Missense Mutation (SNP) | VAF 140/399 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- LILRA2 | c.973T>C p.S325P | Missense Mutation (SNP) | VAF 140/526 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.369); called by muse, varscan2
- LRRN4 | c.155C>A p.P52H | Missense Mutation (SNP) | VAF 71/218 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- MAGEC1 | c.1664G>T p.G555V | Missense Mutation (SNP) | VAF 34/324 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- MAP3K21 | c.365_372del p.E122Gfs*129 | Frame Shift Del (DEL) | VAF 54/212 reads (25%) | called by mutect2, pindel, varscan2
- MBD6 | c.1986_1988del p.L663del | In Frame Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- METTL24 | c.691G>C p.D231H | Missense Mutation (SNP) | VAF 163/567 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- MMS22L | c.3041A>G p.N1014S | Missense Mutation (SNP) | VAF 117/331 reads (35%) | SIFT tolerated (0.99); PolyPhen benign (0.053); called by muse, varscan2
- NHSL1 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 90/289 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OR4Q2 | c.828del p.T277Pfs*4 | Frame Shift Del (DEL) | VAF 93/298 reads (31%) | called by pindel, varscan2
- PEX1 | c.1801A>C p.K601Q | Missense Mutation (SNP) | VAF 135/470 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PLEKHM2 | c.659A>T p.D220V | Missense Mutation (SNP) | VAF 56/175 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PLPP1 | c.800C>A p.T267N | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPFIA2 | c.3287A>T p.E1096V | Missense Mutation (SNP) | VAF 72/202 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- RAD51 | c.861_875del p.G288_I292del | In Frame Del (DEL) | VAF 139/626 reads (22%) | called by mutect2, pindel, varscan2
- RBMXL3 | c.2827T>A p.Y943N | Missense Mutation (SNP) | VAF 70/230 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- RIMS1 | c.740C>A p.P247H | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.401); called by muse, varscan2
- SERPINB5 | c.1007T>G p.V336G | Missense Mutation (SNP) | VAF 152/514 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, varscan2
- SFI1 | c.1806-1G>T p.X602_splice (on ENST00000400288 / NM_001007467.3; = p.X571_splice on NM_014775.4) | Splice Site (SNP) | VAF 24/74 reads (32%) | called by muse, varscan2
- SHISA9 | c.564-1G>C p.X188_splice | Splice Site (SNP) | VAF 136/249 reads (55%) | called by muse, mutect2, varscan2
- SIRT1 | c.581T>C p.I194T | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.013); called by muse, varscan2
- SLC27A4 | c.567G>C p.E189D | Missense Mutation (SNP) | VAF 168/581 reads (29%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- SNF8 | c.29_54+3del p.X10_splice | Splice Site (DEL) | VAF 36/266 reads (14%) | called by mutect2, pindel
- SSMEM1 | c.672G>T p.M224I | Missense Mutation (SNP) | VAF 117/332 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SUPT16H | c.2371A>C p.T791P | Missense Mutation (SNP) | VAF 76/265 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- TBC1D5 | c.600_604del p.L201* | Frame Shift Del (DEL) | VAF 23/87 reads (26%) | called by mutect2, pindel, varscan2
- TDP2 | c.812_814del p.T271del | In Frame Del (DEL) | VAF 43/179 reads (24%) | called by mutect2, pindel, varscan2
- TDRD6 | c.2914del p.L972Yfs*11 | Frame Shift Del (DEL) | VAF 63/220 reads (29%) | called by mutect2, pindel, varscan2
- TRAJ35 | c.11T>G p.F4C | Missense Mutation (SNP) | VAF 120/368 reads (33%) | called by muse, mutect2, varscan2
- TTN | c.63242del p.N21081Ifs*5 (on ENST00000591111; = p.N13657Ifs*5 on NM_003319.4) | Frame Shift Del (DEL) | VAF 72/266 reads (27%) | called by mutect2, pindel, varscan2
- UNC5D | c.570+1G>T p.X190_splice | Splice Site (SNP) | VAF 74/176 reads (42%) | called by muse, mutect2, varscan2
- WDFY3 | c.6107G>T p.G2036V | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- WIZ | c.46_57del p.Q16_E19del | In Frame Del (DEL) | VAF 78/275 reads (28%) | called by mutect2, pindel*, varscan2*
- ZBTB37 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 14/368 reads (4%) | called by muse, mutect2
- ZBTB4 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- ZNF473 | c.2077G>T p.E693* | Nonsense Mutation (SNP) | VAF 15/403 reads (4%) | called by muse, mutect2
- ZNF850 | c.1398A>T p.Q466H | Missense Mutation (SNP) | VAF 99/333 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- ARPC5L | c.207G>A p.K69= | Silent (SNP) | VAF 81/283 reads (29%) | called by muse, mutect2, varscan2
- CORO6 | c.1386C>T p.N462= | Silent (SNP) | VAF 30/100 reads (30%) | called by muse, mutect2, varscan2
- FREM2 | c.4959C>T p.N1653= | Silent (SNP) | VAF 43/133 reads (32%) | called by muse, mutect2, varscan2
- FRMD7 | c.1674C>T p.S558= | Silent (SNP) | VAF 38/803 reads (5%) | catalogued as rs369003419; called by muse, mutect2
- GPR3 | c.558G>A p.V186= | Silent (SNP) | VAF 140/400 reads (35%) | catalogued as rs1341339786; called by muse, mutect2, varscan2
- HCFC1 | c.570C>T p.P190= | Silent (SNP) | VAF 89/278 reads (32%) | called by muse, mutect2, varscan2
- IFT81 | c.1224T>C p.S408= | Silent (SNP) | VAF 73/231 reads (32%) | called by muse, mutect2, varscan2
- IPO13 | c.1956C>T p.D652= | Silent (SNP) | VAF 71/272 reads (26%) | catalogued as rs1333215850; called by muse, mutect2, varscan2
- JPH1 | c.447C>T p.Y149= | Silent (SNP) | VAF 63/124 reads (51%) | catalogued as rs964410638, COSV100646698; called by muse, mutect2, varscan2
- PLXNB2 | c.2061C>T p.F687= | Silent (SNP) | VAF 149/500 reads (30%) | catalogued as COSV63782693; called by muse, varscan2
- PRC1 | c.1653C>A p.L551= | Silent (SNP) | VAF 36/115 reads (31%) | called by muse, mutect2, varscan2
- SLC9A1 | c.1035C>T p.A345= | Silent (SNP) | VAF 100/345 reads (29%) | catalogued as rs777836201; called by muse, mutect2, varscan2
- SNX9 | c.63G>A p.T21= | Silent (SNP) | VAF 51/153 reads (33%) | catalogued as rs149713097; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500787 T>C | 5'Flank (SNP) | VAF 117/413 reads (28%) | catalogued as rs768692427; called by muse, mutect2, varscan2
- BRD1 | c.2360-275A>T | Intron (SNP) | VAF 98/355 reads (28%) | called by muse, mutect2, varscan2
- CORIN | c.2068+148G>A | Intron (SNP) | VAF 73/292 reads (25%) | catalogued as rs1358448919; called by muse, mutect2, varscan2
- DCTN3 | c.412-85G>A | Intron (SNP) | VAF 34/93 reads (37%) | called by muse, mutect2, varscan2
- GK5 | c.1441+72A>C | Intron (SNP) | VAF 90/247 reads (36%) | called by muse, mutect2, varscan2
- MAPT | c.220+2518G>T | Intron (SNP) | VAF 89/294 reads (30%) | called by muse, mutect2, varscan2
- PTEN | c.79+11C>T | Intron (SNP) | VAF 164/505 reads (32%) | catalogued as rs1564801923, COSV64310539; ClinVar: likely benign; called by muse, mutect2, varscan2
- RPL7A | c.3+17T>A | Intron (SNP) | VAF 69/237 reads (29%) | called by muse, mutect2, varscan2
- SETD9 | c.98+582G>A | Intron (SNP) | VAF 64/256 reads (25%) | called by muse, mutect2, varscan2
